Gene-level copy-number profile of tumor specimen TARGET-20-PARMME-09A from TARGET case TARGET-20-PARMME, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.5 years (3,832 days).
Specimen TARGET-20-PARMME-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-AML.1381d52f-758f-511e-b659-2d28b33aff23.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-20-PARMME-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 387 have no estimate.
https://portal.gdc.cancer.gov/files/3a781b51-576c-4f54-b665-9b4ac6823b6c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 586; copy number 1: 8; copy number 2: 59,455; copy number 3: 109; copy number 4: 1; copy number 5: 35; copy number 9: 42.

Homozygous deletions (total copy number 0; autosomes only): 65 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,275,298–90,221,384, 48 genes: IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38, IGKV1-39, IGKV2-40, AC006453.3, LSP1P5, 5S_rRNA, AC006453.1, AC006453.2, AC006453.4, IGKV2D-40, IGKV1D-39, IGKV2D-38, IGKV1D-37, IGKV2D-36, IGKV1D-35, IGKV3D-34, IGKV1D-33, IGKV1D-32, IGKV3D-31, IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8.
- chr2:195,003,711–195,026,370, 1 gene (within-gene range 0–2): AC010983.1.
- chr3:133,746,040–133,796,641, 1 gene (within-gene range 0–2): TF.
- chr8:43,672,823–43,674,591, 2 genes: AC139365.2, AC139365.1.
- chr11:54,591,480–54,725,816, 11 genes: OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P.
- chr11:58,387,583–58,388,486, 1 gene: OR5B15P.
- chr11:135,061,781–135,075,908, 1 gene: LINC02684.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 77 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 9 (within-gene range 2–9): AC244205.1.
- chr2:88,857,161–89,268,506, 41 genes, copy number 9: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33.
- chr16:35,207,884–35,284,146, 1 gene, copy number 5 (within-gene range 2–5): AC023824.3.
- chr16:35,232,412–35,529,318, 28 genes, copy number 5: FGFR3P5, FRG2JP, RARRES2P6, AGGF1P8, FRG2HP, RARRES2P9, AGGF1P9, C2orf69P4, LINC01566, FRG2GP, AGGF1P4, FRG2IP, RARRES2P7, AGGF1P5, C2orf69P3, AC018558.4, ZNF971P, AC018558.6, FRG2DP, RARRES2P10, AGGF1P6, AC018558.2, C2orf69P2, AC018558.3, AC018558.7, AC018558.1, TP53TG3HP, AC018558.5.
- chr17:46,029,916–46,225,389, 1 gene, copy number 5 (within-gene range 2–5): KANSL1.
- chr17:46,193,576–46,268,694, 5 genes, copy number 5: KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1.

Autosomal genes at a single copy (total copy number 1): 8. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
